CGCI case HTMCP-01-17-00565 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/34bdda00-df38-4a61-979d-a2563ac62d2b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 661 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: primary; Age at diagnosis: 56.1 years (20,482 days); Year of diagnosis: 2018; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage II; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 637 days (1.7 years); Max tumor bulk site: Cervical lymph nodes.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%; Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS; Lymph nodes tested: 1; Tumor largest dimension diameter: 5 cm.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (7 entries)
- Days to follow up: 0 days; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 79 days; Disease response: With Tumor.
- Days to follow up: 223 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 223 days.
- Days to follow up: 359 days; Disease response: Tumor Free; Imaging type: PET; Imaging result: Positive.
- Days to follow up: 450 days (1.2 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 450 days (1.2 years).
- Days to follow up: 637 days (1.7 years); Disease response: With Tumor.
- Imaging type: PET; Imaging result: Positive.

Molecular and laboratory tests
- BCL2 (Flow Cytometry): Positive.
- BCL2 (IHC): Positive.
- BCL6 (Flow Cytometry): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (Flow Cytometry): Positive; Specialized molecular test: CD10 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD19 (Flow Cytometry): Positive.
- CD20 (Flow Cytometry): Positive.
- CD20 (IHC): Positive.
- CD23 (Flow Cytometry): Negative.
- CD3 (IHC): Negative.
- CD30 (Flow Cytometry): Positive.
- CD5 (Flow Cytometry): Negative.
- CD79A (Flow Cytometry): Positive.
- CD79A (IHC): Positive.
- IGK: Abnormal, NOS; Clonality: Clonal.
- IRF4 (Flow Cytometry): Positive; Specialized molecular test: MUM1 > 30%.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Negative; Specialized molecular test: P53 > 20%.
- Test (Flow Cytometry): Negative; Specialized molecular test: EBER.
- Test (Flow Cytometry): Positive; Specialized molecular test: Surface Ig.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 183 [Blood test normal range upper: 250].

Other clinical attributes
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Weight: 111.1 kg; Height: 200.6 cm; BMI: 27.6; CD4 count: 217; Haart treatment indicator: Yes.
- Day 0: Comorbidities: Hepatitis B Infection.
- Day 0: Risk factors: Hepatitis B Infection.
- Day 79: Nadir CD4 count: 112.
- Risk factors: HIV/AIDS.
- Comorbidities: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples)
- Sample HTMCP-01-17-00565-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-17-00565-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 1; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- History of disease: Year of HIV diagnosis: 1987; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact; History relevant infectious diagnosis: Hepatitis B Virus.
- Primary pathology: Follicular component percent: < or = 10%; Tumor resected max dimension: 5.0; Method initial path diagnosis: Biopsy (all types); Lymph nodes examined: Yes.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: No Known Extranodal Involvement.
- Tests performed: LDH level: 183; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: CD23.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: CD79a.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic testing results, Genetic testing result 10: Immunophenotypic analysis tested: CD30.
- Tests performed, Genetic testing results, Genetic testing result 12: Immunophenotypic analysis tested: Eber.
- Follow-up form 1: Treatment outcome first course: Progressive Disease; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Treatment outcome first course: Progressive Disease; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-17-00565-01A-01E-14168:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-17-00565-01A-01S-14168:
- % tumour top: 90
- % tumour bottom: 90
